Somatic mutation profile of tumor specimen TCGA-HT-7677-01A (aliquot TCGA-HT-7677-01A-11D-2253-08) from TCGA case TCGA-HT-7677, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 53.7 years (19,610 days).
Specimen TCGA-HT-7677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18ac02a8-bd41-4c18-8de2-6796d12f3125.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7677-10A (Blood Derived Normal), aliquot TCGA-HT-7677-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ddf4656-2698-4178-b8b6-ea7bcf5a1fac

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Del 5, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>T p.R1512L | Missense Mutation (SNP) | VAF 62/90 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CFHR3 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.713); catalogued as rs574536456, COSV66401862; called by muse, mutect2, varscan2
- CYP2C19 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs138142612; ClinVar: drug response; called by muse, mutect2, varscan2
- DMRTA1 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240594001, COSV57924042, COSV57924501; called by muse, mutect2, varscan2
- DSC2 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs180863872, COSV51862683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMG1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs782418214, COSV54641500; called by muse, mutect2, varscan2
- EYA4 | c.438-2A>T p.X146_splice | Splice Site (SNP) | VAF 30/236 reads (13%) | catalogued as COSV62049139; called by muse, mutect2, varscan2
- F5 | c.1115A>G p.D372G | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV63122461; called by muse, mutect2, varscan2
- FCHO1 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53181720, COSV53184721; called by muse, mutect2, varscan2
- FHL5 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.118); catalogued as COSV58736670; called by muse, mutect2, varscan2
- FLNC | c.6082C>T p.P2028S | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57952205; called by muse, mutect2
- FUBP1 | c.647del p.G216Efs*6 | Frame Shift Del (DEL) | VAF 49/95 reads (52%) | catalogued as COSV53935290; called by mutect2, pindel, varscan2
- IL17C | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs775359432, COSV54918328; called by muse, mutect2, varscan2
- MRAP | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs755085204, COSV57936565; called by muse, mutect2, varscan2
- OR52B6 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763385936, COSV61447624; called by muse, mutect2, varscan2
- PRKDC | c.5083C>G p.L1695V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV58048040; called by muse, mutect2
- PTPN9 | c.1573T>G p.F525V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60723201; called by muse, mutect2, varscan2
- RARS2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV65760612; called by muse, mutect2, varscan2
- SOX17 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV52025076; called by muse, mutect2, varscan2
- SPTBN1 | c.3719A>G p.N1240S | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV61687063; called by muse, mutect2
- TRAF7 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV58213553; called by muse, mutect2, varscan2
- UBC | c.1171A>G p.K391E | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV60058977; called by muse, mutect2
- XIRP1 | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs371572701; called by mutect2, varscan2
- ARID1B | c.2757del p.P920Rfs*6 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | called by mutect2, pindel, varscan2
- GRB10 | c.770del p.N257Ifs*3 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR7A17 | c.884_885del p.K295Rfs*23 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- TRIP12 | c.5314_5315del p.L1773Tfs*15 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | called by pindel, varscan2
- CA11 | c.429C>T p.A143= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV50032871; called by muse, mutect2
- DDX39B | c.354G>A p.V118= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV63331151; called by muse, mutect2, varscan2
- FGD5 | c.1995G>A p.T665= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs371257394; called by muse, mutect2, varscan2
- HCAR1 | c.174C>T p.A58= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs747599543, COSV63672923; called by muse, mutect2, varscan2
- HVCN1 | c.177C>G p.P59= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV54371669; called by muse, mutect2, varscan2
- MIDN | c.849C>T p.T283= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV56294694; called by muse, mutect2
- MROH6 | c.70C>T p.L24= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- NPSR1 | c.153G>A p.E51= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV62198760; called by muse, mutect2, varscan2
- SCN3A | c.4740C>G p.L1580= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs754806515, COSV51806089; called by muse, mutect2, varscan2
